Somatic mutation profile of tumor specimen TCGA-B0-5713-01A (aliquot TCGA-B0-5713-01A-11D-1669-08) from TCGA case TCGA-B0-5713, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 75.7 years (27,644 days).
Specimen TCGA-B0-5713-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 33b4efa1-c340-469c-9017-0ce2f84696b5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-5713-11A (Solid Tissue Normal), aliquot TCGA-B0-5713-11A-01D-1669-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f97f5cae-69d6-498b-a329-f25a0ab71f0a

The open-access MAF lists 107 somatic variants for this specimen: 90 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, Silent 16, Frame Shift Del 10, Frame Shift Ins 5, Splice Site 3, Nonsense Mutation 2, Nonstop Mutation 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGF3 | c.283C>T p.R95W | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs281860303, CM098984, COSV61925996; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- VHL | c.464-2A>G p.X155_splice | Splice Site (SNP) | VAF 11/22 reads (50%) | hotspot (GDC flag); catalogued as rs5030816, CS941546, CS961704, CS961705, COSV56547121, COSV56551502, COSV56558899, COSV56563919; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADCY5 | c.2062C>A p.Q688K | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.216); catalogued as COSV59198196; called by muse, mutect2, varscan2
- API5 | c.83A>G p.Y28C | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66633339; called by muse, mutect2
- ATG13 | c.134C>A p.P45Q | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV56319516; called by muse, mutect2, varscan2
- ATRX | c.1624G>C p.V542L | Missense Mutation (SNP) | VAF 51/518 reads (10%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.001); catalogued as COSV64876895; called by muse, mutect2
- BCL6 | c.794T>A p.I265N | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (0.56); PolyPhen benign (0.006); catalogued as COSV51652304; called by muse, mutect2, varscan2
- CDHR5 | c.467A>G p.K156R | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.288); catalogued as COSV51564341; called by muse, mutect2, varscan2
- CEP95 | c.469G>C p.G157R | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.175); catalogued as COSV73609193; called by muse, mutect2
- CFAP43 | c.3266T>G p.I1089S | Missense Mutation (SNP) | VAF 43/143 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as COSV63853177; called by muse, mutect2, varscan2
- CRIP3 | c.55A>G p.S19G | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.829); catalogued as COSV51484036; called by muse, mutect2, varscan2
- CUL7 | c.1594G>A p.E532K | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); catalogued as COSV54817243; called by muse, mutect2, varscan2
- DNAH17 | c.2663A>G p.N888S | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs1217289258, COSV67754191; called by muse, mutect2, varscan2
- EFTUD2 | c.781G>T p.D261Y | Missense Mutation (SNP) | VAF 64/226 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68183146; called by muse, mutect2, varscan2
- EGFR | c.2414A>G p.H805R | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV51801505; called by muse, mutect2, varscan2
- EP300 | c.498C>A p.N166K | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.689); catalogued as COSV54333032; called by muse, mutect2, varscan2
- FAM83B | c.75G>C p.K25N | Missense Mutation (SNP) | VAF 54/172 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60922233; called by muse, mutect2, varscan2
- FAT1 | c.4799C>G p.S1600W | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV71674175; called by muse, mutect2, varscan2
- FGD6 | c.2632G>T p.E878* | Nonsense Mutation (SNP) | VAF 30/142 reads (21%) | catalogued as COSV59693390; called by muse, mutect2, varscan2
- FMOD | c.938C>A p.T313N | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.939); catalogued as COSV61610035; called by muse, mutect2, varscan2
- GON4L | c.1947G>T p.E649D | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV55193959; called by muse, mutect2, varscan2
- GPC5 | c.887T>C p.I296T | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as COSV65599812; called by muse, mutect2, varscan2
- GPR62 | c.977T>A p.L326H | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as COSV59054684; called by muse, mutect2, varscan2
- HCN4 | c.2229G>T p.Q743H | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56083702; called by muse, mutect2, varscan2
- HGD | c.418A>G p.T140A | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV52198296; called by muse, mutect2, varscan2
- HNRNPH1 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.61); PolyPhen benign (0.015); catalogued as COSV61485893; called by muse, mutect2, varscan2
- HSP90B1 | c.2369A>C p.E790A | Missense Mutation (SNP) | VAF 42/164 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV55355476; called by muse, mutect2, varscan2
- IRF9 | c.668C>G p.T223S | Missense Mutation (SNP) | VAF 35/176 reads (20%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.902); catalogued as COSV60703243; called by muse, mutect2, varscan2
- ITGAL | c.1262C>T p.A421V | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.267); catalogued as COSV63322265; called by muse, mutect2, varscan2
- KBTBD8 | c.1719G>C p.E573D | Missense Mutation (SNP) | VAF 25/139 reads (18%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.584); catalogued as COSV55128593; called by muse, mutect2, varscan2
- KLK6 | c.626G>A p.G209D | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59565690; called by muse, mutect2
- LIMK1 | c.1624A>C p.I542L | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.335); catalogued as COSV60281670; called by muse, mutect2
- LRP12 | c.1865C>T p.S622L | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.977); catalogued as rs931450580, COSV52628994; called by muse, mutect2, varscan2
- LRRCC1 | c.294G>T p.L98F | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.201); catalogued as COSV64483487; called by muse, mutect2, varscan2
- MAGEB10 | c.997G>A p.G333S | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1212381828, COSV63310687; called by muse, mutect2, varscan2
- MAPK10 | c.425T>C p.L142P (on ENST00000359221 / NM_001351625.2; = p.L180P on NM_002753.5) | Missense Mutation (SNP) | VAF 53/186 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60382644; called by muse, mutect2, varscan2
- MARCKS | c.54G>C p.R18S | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.344); catalogued as COSV64042814; called by muse, mutect2, varscan2
- MCU | c.333T>G p.F111L | Missense Mutation (SNP) | VAF 58/204 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.081); catalogued as COSV64066279; called by muse, mutect2, varscan2
- MIDEAS | c.1337T>A p.L446Q | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.143); catalogued as rs1422030562, COSV54095050; called by muse, mutect2, varscan2
- MLYCD | c.1436A>G p.Q479R | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.798); catalogued as COSV52305293; called by muse, mutect2
- NOL6 | c.398T>C p.L133P | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53041918; called by muse, mutect2, varscan2
- OTUB2 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV52573523; called by muse, mutect2, varscan2
- OXA1L | c.826C>G p.P276A (on ENST00000285848; = p.P216A on NM_005015.5) | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.999); catalogued as COSV53537169; called by muse, mutect2, varscan2
- PAQR8 | c.825T>A p.C275* | Nonsense Mutation (SNP) | VAF 22/63 reads (35%) | catalogued as COSV62442626; called by muse, mutect2, varscan2
- PLD1 | c.2351T>A p.F784Y | Missense Mutation (SNP) | VAF 59/215 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV60568216; called by muse, mutect2, varscan2
- PRNP | c.662A>G p.E221G | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.776); catalogued as COSV65173739; called by muse, mutect2, varscan2
- PXDNL | c.886A>G p.R296G | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.21); catalogued as COSV62487640; called by muse, mutect2, varscan2
- RAB11FIP3 | c.668G>T p.R223L | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.633); catalogued as rs1246061102, COSV51933630; called by muse, mutect2, varscan2
- RAB24 | c.547+1G>A p.X183_splice | Splice Site (SNP) | VAF 41/140 reads (29%) | catalogued as COSV100293675, COSV57463321; called by muse, mutect2, varscan2
- RER1 | c.478A>G p.I160V | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.096); catalogued as rs367686071; called by muse, mutect2, varscan2
- SERPINA12 | c.299A>T p.Q100L | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.152); catalogued as COSV57943787; called by muse, mutect2, varscan2
- SIPA1L1 | c.860A>T p.K287I | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV62170326; called by muse, mutect2, varscan2
- SLC26A11 | c.305T>G p.L102R | Missense Mutation (SNP) | VAF 55/223 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58339298; called by muse, mutect2, varscan2
- SLCO4C1 | c.983T>C p.L328S | Missense Mutation (SNP) | VAF 60/139 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as COSV60515883; called by muse, mutect2, varscan2
- SNRPB | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs778892584, COSV60015031; called by muse, mutect2, varscan2
- SPATA32 | c.701C>A p.P234Q | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.201); catalogued as COSV59303815; called by muse, mutect2, varscan2
- SPG21 | c.133C>A p.P45T | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52602688; called by muse, mutect2, varscan2
- STAB2 | c.2003C>A p.T668K | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.116); catalogued as COSV66339295; called by muse, mutect2
- SVEP1 | c.7031T>A p.V2344D | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as rs764705619, COSV52839495; called by muse, mutect2, varscan2
- TAS2R42 | c.12A>C p.E4D | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV62084623; called by muse, mutect2, varscan2
- TCF3 | c.401G>A p.S134N | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.968); catalogued as COSV53648689; called by muse, mutect2
- THAP9 | c.1333G>A p.V445M | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as rs749695282, COSV56356502; called by muse, mutect2, varscan2
- TLL1 | c.2020G>C p.D674H | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50281562; called by muse, mutect2, varscan2
- TM9SF2 | c.1708T>A p.S570T | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as COSV64506761; called by muse, mutect2, varscan2
- TMC5 | c.1295A>G p.Q432R (on ENST00000396229 / NM_001105248.1; = p.Q186R on NM_024780.5) | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.94); catalogued as COSV54904286; called by muse, mutect2, varscan2
- TMEM169 | c.894A>T p.*298Yext*18 | Nonstop Mutation (SNP) | VAF 23/72 reads (32%) | catalogued as COSV55265321; called by muse, mutect2, varscan2
- TNKS | c.2126A>C p.D709A | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); catalogued as COSV60058074; called by muse, mutect2, varscan2
- TOPBP1 | c.4106G>T p.R1369I | Missense Mutation (SNP) | VAF 12/139 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV53436110; called by muse, mutect2
- TPM2 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.624); catalogued as rs775561043, COSV61406089; called by muse, mutect2, varscan2
- TRAPPC8 | c.272A>T p.D91V | Missense Mutation (SNP) | VAF 55/202 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as COSV51971302; called by muse, mutect2, varscan2
- UBE2J1 | c.728C>A p.P243H | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as COSV70561456; called by muse, mutect2, varscan2
- ZNF185 | c.1639A>T p.T547S | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.055); catalogued as COSV59276022; called by muse, mutect2, varscan2
- ZNF226 | c.2120A>G p.Y707C | Missense Mutation (SNP) | VAF 6/147 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.806); catalogued as COSV56196639; called by muse, mutect2
- ACD | c.113dup p.R39Sfs*81 | Frame Shift Ins (INS) | VAF 8/24 reads (33%) | called by mutect2, varscan2
- ARID1A | c.5181_5182del p.F1728Wfs*7 | Frame Shift Del (DEL) | VAF 71/307 reads (23%) | called by mutect2, pindel, varscan2
- C3orf38 | c.369del p.Q124Nfs*4 | Frame Shift Del (DEL) | VAF 16/61 reads (26%) | called by mutect2, pindel*
- CACNA2D4 | c.150del p.S51Rfs*9 | Frame Shift Del (DEL) | VAF 10/31 reads (32%) | called by mutect2, pindel, varscan2
- CHST12 | c.1229del p.N410Tfs*19 | Frame Shift Del (DEL) | VAF 15/86 reads (17%) | called by mutect2, pindel, varscan2
- KNG1 | c.1929_1930del p.S644Lfs*3 | Frame Shift Del (DEL) | VAF 20/91 reads (22%) | called by mutect2, pindel, varscan2
- PBRM1 | c.835dup p.I279Nfs*8 | Frame Shift Ins (INS) | VAF 6/18 reads (33%) | called by mutect2, varscan2
- PDZD2 | c.4476del p.A1493Pfs*12 | Frame Shift Del (DEL) | VAF 7/45 reads (16%) | called by mutect2, pindel, varscan2
- PLEKHA1 | c.746+2_746+6del p.X249_splice | Splice Site (DEL) | VAF 13/67 reads (19%) | called by mutect2, pindel, varscan2
- PPFIA4 | c.1850del p.N617Tfs*2 (on ENST00000447715; = p.N618Tfs*2 on NM_001304331.2 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 19/72 reads (26%) | called by mutect2, pindel, varscan2
- RNF145 | c.654_660dup p.L221Nfs*39 (on ENST00000424310 / NM_001199383.2; = p.L249Nfs*39 on NM_144726.2) | Frame Shift Ins (INS) | VAF 20/88 reads (23%) | called by mutect2, varscan2
- RPH3AL | c.181_182dup p.A62Gfs*23 | Frame Shift Ins (INS) | VAF 29/108 reads (27%) | called by mutect2, pindel, varscan2
- RPLP0 | c.707del p.S236* | Frame Shift Del (DEL) | VAF 10/53 reads (19%) | called by mutect2, pindel, varscan2
- SDHAF3 | c.7_14delinsCC p.G3_H5delinsP | In Frame Del (DEL) | VAF 26/122 reads (21%) | called by pindel, varscan2*
- SPESP1 | c.478del p.R160Efs*25 | Frame Shift Del (DEL) | VAF 23/118 reads (19%) | called by mutect2, pindel, varscan2
- TCOF1 | c.3411dup p.K1138Qfs*4 (on ENST00000377797 / NM_001135243.1; = p.K1061Qfs*4 on NM_000356.4) | Frame Shift Ins (INS) | VAF 21/117 reads (18%) | called by mutect2, pindel, varscan2
- ZNF761 | c.427del p.S143Afs*23 | Frame Shift Del (DEL) | VAF 52/201 reads (26%) | called by mutect2, pindel, varscan2
- ATP11C | c.2928G>A p.G976= | Silent (SNP) | VAF 35/130 reads (27%) | catalogued as COSV100557489, COSV59564210; called by muse, mutect2, varscan2
- ATP8B1 | c.6T>C p.S2= | Silent (SNP) | VAF 79/287 reads (28%) | catalogued as COSV52175952; called by muse, mutect2, varscan2
- COPS5 | c.441T>C p.L147= | Silent (SNP) | VAF 43/83 reads (52%) | catalogued as COSV63474464; called by muse, mutect2, varscan2
- CORO7 | c.2364G>A p.T788= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as rs151072609, COSV52030272; called by muse, mutect2, varscan2
- ESPL1 | c.5616C>T p.L1872= | Silent (SNP) | VAF 114/288 reads (40%) | catalogued as COSV54475545; called by muse, mutect2, varscan2
- GPKOW | c.126T>A p.S42= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV50242746; called by muse, mutect2, varscan2
- MSH4 | c.78T>C p.P26= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as COSV54203201; called by muse, mutect2, varscan2
- NRBP1 | c.357T>C p.D119= | Silent (SNP) | VAF 106/401 reads (26%) | catalogued as COSV51994277; called by muse, mutect2, varscan2
- PLPPR4 | c.927T>C p.Y309= | Silent (SNP) | VAF 11/150 reads (7%) | catalogued as COSV64565878; called by muse, mutect2
- PNPLA6 | c.1809C>T p.T603= (on ENST00000414982 / NM_001166111.2; = p.T555= on NM_006702.5) | Silent (SNP) | VAF 27/112 reads (24%) | catalogued as rs777094653, COSV55378582; called by muse, mutect2, varscan2
- PTPN18 | c.294C>T p.S98= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as rs1475359848, COSV51559020; called by muse, mutect2, varscan2
- RAD51AP2 | c.132C>A p.V44= | Silent (SNP) | VAF 52/190 reads (27%) | catalogued as COSV67588107; called by muse, mutect2, varscan2
- REXO2 | c.285T>C p.D95= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as rs199983925, COSV56276958; called by muse, mutect2, varscan2
- SYT16 | c.18G>A p.A6= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as rs373261948; called by muse, mutect2, varscan2
- ZFP90 | c.1809T>C p.H603= | Silent (SNP) | VAF 58/225 reads (26%) | catalogued as COSV68050965; called by muse, mutect2, varscan2
- ZNF786 | c.354T>A p.P118= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV100302784, COSV60276140; called by muse, mutect2, varscan2
- C12orf77 | n.233G>C | RNA (SNP) | VAF 7/131 reads (5%) | called by muse, mutect2
